Somatic mutation profile of tumor specimen TCGA-LB-A9Q5-01A (aliquot TCGA-LB-A9Q5-01A-11D-A397-08) from TCGA case TCGA-LB-A9Q5, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 63.6 years (23,218 days).
Specimen TCGA-LB-A9Q5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb342b9f-3aae-4228-bf9d-a66d2efc40bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LB-A9Q5-10A (Blood Derived Normal), aliquot TCGA-LB-A9Q5-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1b2157f-12c7-4780-9f6e-16c73c248e88

The open-access MAF lists 14 somatic variants for this specimen: 14 protein-altering or splice-affecting.
By variant classification: Missense Mutation 14.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.12808T>C p.F4270L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101291241; called by muse, mutect2
- AC013489.1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs138430376, COSV99183840; called by muse, mutect2, varscan2
- CNNM4 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100998634, COSV100998714; called by muse, mutect2
- MLKL | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 18/538 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as COSV100087242; called by muse, mutect2
- PHACTR3 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 10/261 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1332569140, COSV63025673; called by muse, mutect2
- PKD1 | c.4918G>A p.G1640S | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.153); catalogued as rs781184044, COSV51917444, COSV99239279; called by muse, mutect2, varscan2
- RHOC | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 23/441 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766734264, COSV99588028; called by muse, mutect2
- ROBO4 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs749338809, COSV60624136; called by muse, mutect2
- SLC26A6 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 15/253 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258136; called by muse, mutect2
- SMAD4 | c.1151G>A p.G384D | Missense Mutation (SNP) | VAF 24/435 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747576; called by muse, mutect2
- TEX15 | c.1103G>A p.G368E (on ENST00000256246; = p.G751E on NM_001350162.2) | Missense Mutation (SNP) | VAF 14/429 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99820982; called by muse, mutect2
- TPD52 | c.539A>C p.K180T (on ENST00000379097 / NM_001025252.3; = p.K140T on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100990740; called by muse, mutect2
- ZNF513 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 35/1047 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.384); catalogued as COSV99277372; called by muse, mutect2
- PPP4R3A | c.1702G>A p.E568K (on ENST00000554943 / NM_001366432.1; = p.E555K on NM_001284280.1) | Missense Mutation (SNP) | VAF 10/328 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); called by muse, mutect2
